Somatic mutation profile of tumor specimen TCGA-D7-A6EY-01A (aliquot TCGA-D7-A6EY-01A-21D-A31L-08) from TCGA case TCGA-D7-A6EY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 72.6 years (26,526 days).
Specimen TCGA-D7-A6EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd902ca-230a-49fb-abc7-0afea73bc7e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A6EY-10A (Blood Derived Normal), aliquot TCGA-D7-A6EY-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/194aeb04-0aab-4d07-95a3-37fe4d493ed6

The open-access MAF lists 1,598 somatic variants for this specimen: 1,237 protein-altering or splice-affecting, 314 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 852, Silent 314, Frame Shift Del 270, Frame Shift Ins 48, Nonsense Mutation 27, Splice Site 19, Intron 15, RNA 13, 3'UTR 9, In Frame Del 9, Splice Region 8, 5'Flank 5.

Variants (750 of 1,598; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG6 | c.634dup p.C212Lfs*9 | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as rs879133727; ClinVar: likely pathogenic; called by mutect2, varscan2
- ASS1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs762387914, CM940127, COSV61689665; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD8 | c.4611del p.V1538* (on ENST00000646647 / NM_001170629.2; = p.V1259* on NM_020920.4) | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs1555314317; ClinVar: likely pathogenic; called by mutect2, pindel
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- COL4A5 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569488426, CM129358, COSV60361481; ClinVar: pathogenic; called by muse, mutect2
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 32/158 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2, varscan2
- ERBB2 | c.1976T>A p.V659D | Missense Mutation (SNP) | VAF 19/237 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99509015; called by muse, mutect2
- ERBB2 | c.2584A>G p.T862A | Missense Mutation (SNP) | VAF 7/122 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54062276; called by muse, mutect2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 35/200 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15640C>T p.R5214C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123728, CM114916, COSV56407525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.3085C>T p.R1029* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as rs145420388, CM020725, COSV101370819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MPV17 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs121909721, CM061857, COSV99274548; ClinVar: pathogenic; called by muse, mutect2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 6/15 reads (40%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- RPE65 | c.1067del p.N356Mfs*17 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs281865520, CD972436; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AADAC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs762922385, COSV99233496; called by muse, mutect2, varscan2
- AARS2 | c.706del p.Q236Sfs*3 | Frame Shift Del (DEL) | VAF 30/142 reads (21%) | catalogued as rs1253616133; called by mutect2, pindel, varscan2
- ABCA13 | c.3770T>C p.L1257P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101330169; called by muse, mutect2, varscan2
- ABCA13 | c.15034T>G p.F5012V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101291429; called by muse, mutect2
- ABCA3 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764954705, COSV100069104, COSV57061459; called by muse, mutect2, varscan2
- ABCA7 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as COSV99566619; called by muse, mutect2, varscan2
- ABCC10 | c.3736G>A p.V1246M (on ENST00000372530 / NM_001198934.2; = p.V1218M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs764581144, COSV55085725; called by muse, mutect2, varscan2
- ABCG1 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100494503; called by muse, mutect2, varscan2
- ABCG1 | c.1285T>G p.S429A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV100494506; called by muse, mutect2, varscan2
- ABHD11 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs142499119; called by muse, mutect2, varscan2
- ABITRAM | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV100534649; called by muse, mutect2, varscan2
- ABL1 | c.1801A>G p.S601G | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV100584568; called by muse, varscan2
- AC004922.1 | c.1297T>G p.C433G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV99403078; called by muse, mutect2
- AC098582.1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs1351209942, COSV99985986; called by muse, mutect2, varscan2
- ACADVL | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.357); catalogued as COSV99138839; called by muse, mutect2, varscan2
- ACCSL | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs547162461, COSV101122290; called by muse, mutect2, varscan2
- ACKR4 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs139794831; called by muse, mutect2
- ACMSD | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99299457; called by muse, mutect2, varscan2
- ACOT2 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1173801451, COSV53150772; called by muse, mutect2, varscan2
- ACSS3 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772788931, COSV54083770; called by muse, mutect2, varscan2
- ACTL7A | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758729154, COSV61776227; called by muse, mutect2, varscan2
- ACTN3 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.363); catalogued as COSV101557884; called by muse, mutect2, varscan2
- ACTN3 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1428006874, COSV101557885; called by muse, mutect2, varscan2
- ACTN3 | c.2671T>G p.F891V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100074488; called by muse, mutect2
- ACTN4 | c.2696A>G p.K899R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99400717; called by muse, mutect2
- ACTR1A | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs1417170496, COSV64023448; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 42/111 reads (38%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM17 | c.2468_2469del p.E823Vfs*4 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs781314197; called by pindel, varscan2
- ADAM22 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs773391403, COSV55975554; called by muse, mutect2, varscan2
- ADAMTS10 | c.1499G>T p.W500L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99547400; called by muse, mutect2, varscan2
- ADAMTS14 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs1445350270, COSV100941841; called by muse, mutect2, varscan2
- ADAMTS15 | c.2611G>A p.G871R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs776395204, COSV54503298; called by muse, mutect2, varscan2
- ADAMTS18 | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51398784; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTSL1 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs761443595, COSV65900222; called by muse, mutect2, varscan2
- ADCY8 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs774800014, COSV53914076; called by muse, mutect2, varscan2
- ADCY9 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570837; called by muse, mutect2, varscan2
- ADNP | c.3047dup p.A1017Gfs*6 | Frame Shift Ins (INS) | VAF 20/113 reads (18%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.2057A>C p.H686P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100823849; called by muse, mutect2
- ADORA2A | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs199666600; called by muse, mutect2, varscan2
- ADPRS | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV99255629; called by muse, mutect2, varscan2
- ADRA2B | c.636del p.P213Lfs*140 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs756613487; called by mutect2, pindel, varscan2
- AFDN | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 38/214 reads (18%) | catalogued as COSV60036499; called by muse, mutect2, varscan2
- AGMAT | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs771473311, COSV101011817, COSV101011831; called by muse, mutect2, varscan2
- AGRP | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as COSV99341335; called by muse, mutect2, varscan2
- AHDC1 | c.1921A>T p.S641C | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99899733; called by muse, mutect2, varscan2
- AHNAK2 | c.15275T>C p.V5092A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100318874; called by muse, mutect2, varscan2
- AIMP2 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs771380350, COSV99552273; called by mutect2, varscan2
- AKAP12 | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs775450726, COSV53579040; called by muse, mutect2, varscan2
- AKNA | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs1169481020, COSV99801011; called by muse, mutect2, varscan2
- AKNA | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV99801013; called by muse, mutect2, varscan2
- AL441992.2 | c.*1078T>C | Splice Region (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100223828; called by muse, mutect2, varscan2
- AL645922.1 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774737044, COSV54963254; called by muse, mutect2, varscan2
- ALDH18A1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64662893; called by muse, mutect2, varscan2
- ALG3 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100201182; called by muse, mutect2, varscan2
- ALLC | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV99377604, COSV99378251; called by muse, mutect2, varscan2
- ALOX12 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs779986334, COSV52351492; called by muse, mutect2, varscan2
- AMOTL2 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.217); catalogued as rs745539705; called by muse, mutect2, varscan2
- ANK3 | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs190358169, COSV99782204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.4607A>G p.D1536G | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99970502; called by muse, mutect2, varscan2
- ANKRD11 | c.4263A>T p.E1421D | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99970539; called by muse, mutect2, varscan2
- ANKRD11 | c.1965A>T p.K655N | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56374810, COSV99970541; called by muse, mutect2
- ANKRD40 | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99560630; called by muse, mutect2, varscan2
- ANKS1A | c.2318dup p.S774* | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | catalogued as rs765484445; called by mutect2, pindel, varscan2
- ANO4 | c.293del p.G98Efs*58 (on ENST00000392977 / NM_001286615.2; = p.G63Efs*58 on NM_178826.4) | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs1566034515; called by mutect2, pindel, varscan2
- ANTXR1 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100363077; called by muse, mutect2, varscan2
- ANXA7 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100873506; called by muse, mutect2, varscan2
- AP2A2 | c.1955T>C p.V652A | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100173322; called by muse, mutect2, varscan2
- AP4E1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1400763861, COSV99957172; called by muse, mutect2, varscan2
- APC | c.7678C>T p.R2560* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV57378917; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP2 | c.4526A>G p.Y1509C | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58292205; called by muse, mutect2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 31/155 reads (20%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGAP2 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100096604; called by muse, mutect2, varscan2
- ARFGAP3 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs202174033, COSV54313278; called by muse, mutect2, varscan2
- ARG2 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.29); catalogued as COSV99373851; called by muse, mutect2, varscan2
- ARHGAP10 | c.855T>A p.S285R | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100331738; called by muse, mutect2, varscan2
- ARHGAP22 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781044438, COSV99985956; called by mutect2, varscan2
- ARHGEF17 | c.1228T>C p.S410P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.136); catalogued as COSV99736710; called by muse, mutect2, varscan2
- ARHGEF40 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.345); catalogued as COSV100070678; called by muse, mutect2, varscan2
- ARID1A | c.6035G>A p.G2012D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100253305; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs776520069; called by mutect2, varscan2
- ARMC12 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs755088430, COSV55362101, COSV99849598; called by muse, mutect2, varscan2
- ARMC2 | c.2322T>A p.D774E | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933653; called by muse, mutect2
- ARMH3 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs1454472679, COSV100899039; called by muse, mutect2, varscan2
- ASB5 | c.444T>A p.S148R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99642086; called by muse, mutect2, varscan2
- ASGR1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352610; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 38/153 reads (25%) | catalogued as rs761154268; called by mutect2, varscan2
- ASPG | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101496444; called by muse, mutect2
- ASXL1 | c.619A>G p.S207G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs1318312862, COSV100041026; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 17/138 reads (12%) | catalogued as rs746676748; called by mutect2, varscan2
- ATN1 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63110676; called by muse, mutect2, varscan2
- ATN1 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs782023721, COSV99980840; called by muse, mutect2, varscan2
- ATP8B3 | c.3254A>G p.H1085R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs1191797442, COSV100034937; called by muse, mutect2
- ATRIP | c.2249A>G p.Q750R (on ENST00000320211 / NM_130384.3; = p.Q723R on NM_032166.4) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99604176; called by muse, mutect2, varscan2
- ATXN2L | c.2135_2137del p.S712del | In Frame Del (DEL) | VAF 10/109 reads (9%) | catalogued as rs1307206763; called by mutect2, pindel
- AXIN2 | c.1571T>A p.V524D | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.104); catalogued as COSV100196918; called by muse, mutect2, varscan2
- AZIN2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs144776558; called by muse, mutect2, varscan2
- B3GALT6 | c.529C>A p.R177S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs1260565985, COSV55418751, COSV55420286; called by muse, mutect2
- BACE2 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100161155; called by muse, mutect2
- BAD | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99657729; called by muse, mutect2, varscan2
- BCAN | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780124787, COSV100228475; called by muse, mutect2, varscan2
- BCL11A | c.1802G>A p.R601H (on ENST00000335712 / NM_001365609.1; = p.R635H on NM_018014.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59625614; called by muse, mutect2, varscan2
- BCL2 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs368344129, COSV100385797; called by muse, mutect2
- BCO1 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99258630; called by muse, mutect2, varscan2
- BDP1 | c.4197G>T p.Q1399H | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100703496; called by muse, mutect2
- BICRAL | c.2675A>C p.N892T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.055); catalogued as rs79987333, COSV100018451; called by muse, mutect2, varscan2
- BIRC2 | c.427T>A p.L143M | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.322); catalogued as COSV99926907; called by muse, mutect2, varscan2
- BIRC2 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99926908; called by muse, mutect2
- BNC1 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100597466; called by muse, mutect2, varscan2
- BOD1L1 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142797611; called by muse, mutect2, varscan2
- BPIFA2 | c.727A>C p.T243P | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.227); catalogued as rs199534853, COSV99488013; called by muse, mutect2, varscan2
- BRD3 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs200460874, COSV57701256, COSV57708013; called by muse, mutect2, varscan2
- BRICD5 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV100064002; called by muse, mutect2
- BRK1 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV99845247; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BTNL8 | c.843A>T p.R281S (on ENST00000340184 / NM_001040462.3; = p.R325* on NM_024850.2) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV99180417, COSV99180574; called by muse, mutect2, varscan2
- C11orf53 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV99724892; called by muse, mutect2, varscan2
- C17orf80 | c.828A>T p.E276D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as COSV99278505; called by muse, mutect2, varscan2
- C19orf12 | c.210dup p.L71Afs*12 (on ENST00000392278 / NM_001031726.3; = p.L60Afs*12 on NM_031448.6) | Frame Shift Ins (INS) | VAF 21/160 reads (13%) | catalogued as rs770374870; called by mutect2, pindel, varscan2
- C1QTNF4 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100209395; called by muse, mutect2
- C1orf109 | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100523729; called by muse, mutect2, varscan2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs780657010; called by mutect2, varscan2
- C2CD2L | c.1018C>T p.L340= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100371486; called by muse, mutect2
- C2CD3 | c.3952C>T p.L1318F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100487386; called by muse, mutect2, varscan2
- C2CD3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs755669837, COSV58095409; called by muse, mutect2, varscan2
- C2CD6 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.022); catalogued as rs764770174, COSV99634550; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C8orf33 | c.479A>G p.H160R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100510627; called by muse, mutect2, varscan2
- C8orf34 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100447834; called by muse, varscan2
- CACNA1E | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62413949, COSV62438536; called by muse, mutect2
- CAMSAP1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754241814, COSV100409641, COSV100410427; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 21/104 reads (20%) | catalogued as rs760711956; called by mutect2, varscan2
- CAPN11 | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291943; called by muse, mutect2
- CAPN5 | c.947A>G p.K316R (on ENST00000456580; = p.K276R on NM_004055.5) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.225); catalogued as COSV99582549; called by muse, mutect2
- CARMIL1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as rs1385108756, COSV61523112; called by muse, mutect2, varscan2
- CARMIL1 | c.3482A>G p.Q1161R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.882); catalogued as COSV100278782; called by muse, mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 15/126 reads (12%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CBX7 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99334208; called by muse, mutect2, varscan2
- CC2D2A | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs747935651, COSV101052919; called by muse, mutect2
- CCAR1 | c.1178A>G p.D393G | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99771393; called by muse, mutect2, varscan2
- CCAR1 | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99771394; called by muse, mutect2, varscan2
- CCAR2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV52386953, COSV99374314; called by muse, mutect2, varscan2
- CCDC114 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs757626365, COSV100197039; called by muse, mutect2, varscan2
- CCDC149 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60882202; called by muse, mutect2, varscan2
- CCDC153 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100501568; called by muse, mutect2, varscan2
- CCDC174 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514268; called by muse, mutect2, varscan2
- CCDC186 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs781536227, COSV100991138; called by muse, mutect2, varscan2
- CCDC22 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100545356; called by muse, mutect2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs749079180; called by mutect2, pindel, varscan2
- CCN4 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs199909788, COSV51535773; called by muse, mutect2
- CCNQ | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs781948889, COSV52344096; called by muse, mutect2, varscan2
- CD274 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV101056135; called by muse, mutect2
- CD7 | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99486373; called by muse, mutect2
- CD84 | c.473A>C p.E158A | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100246260; called by muse, mutect2
- CDC42BPA | c.4674-1G>T p.X1558_splice (on ENST00000334218 / NM_001366019.2; = p.X1545_splice on NM_003607.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100506809; called by muse, mutect2, varscan2
- CDC42BPG | c.4466G>C p.R1489P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as COSV100712155; called by muse, mutect2
- CDH1 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV99932624; called by muse, mutect2, varscan2
- CDH8 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV100184036, COSV54871232; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1247+1del p.X416_splice (on ENST00000357886 / NM_001365728.1; = p.X402_splice on NM_016082.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 38/194 reads (20%) | catalogued as rs965457526; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.2405T>G p.L802R | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100575729; called by muse, mutect2
- CDK5RAP2 | c.998del p.K333Rfs*76 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs973156155; called by mutect2, pindel, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | catalogued as rs753494539; called by mutect2, varscan2
- CDKL3 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV99528103; called by muse, mutect2
- CEACAM5 | c.1802dup p.D602Rfs*19 | Frame Shift Ins (INS) | VAF 40/250 reads (16%) | catalogued as rs782698410; called by mutect2, varscan2
- CELF4 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.407); catalogued as rs764874262, COSV58456162; called by muse, mutect2, varscan2
- CELSR2 | c.3275G>T p.R1092L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99604680; called by muse, mutect2, varscan2
- CENPT | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV99535330; called by muse, mutect2, varscan2
- CEP20 | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99740009; called by muse, mutect2, varscan2
- CES1 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62089049; called by muse, mutect2
- CFAP157 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs757079161, COSV100077083; called by muse, mutect2, varscan2
- CFAP251 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as rs1263029838, COSV99945776; called by muse, mutect2, varscan2
- CGN | c.1076C>A p.A359E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.628); catalogued as COSV99642786; called by muse, mutect2
- CHD7 | c.2293T>C p.F765L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.184); catalogued as COSV101418430; called by muse, mutect2, varscan2
- CHP1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100587177; called by muse, mutect2, varscan2
- CHST6 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1280090242, COSV60000123; called by muse, mutect2, varscan2
- CHST8 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99381120; called by muse, mutect2, varscan2
- CIAPIN1 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101275924; called by muse, mutect2, varscan2
- CIC | c.3283T>G p.F1095V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV99360248; called by muse, mutect2, varscan2
- CLCA4 | c.218del p.F73Sfs*7 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | catalogued as rs745822656; called by mutect2, varscan2
- CLCF1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV56862165; called by muse, mutect2
- CLEC17A | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs753078060, COSV60426952; called by muse, mutect2
- CLK2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs757792688, COSV62876539; called by muse, mutect2, varscan2
- CLTB | c.671A>T p.Q224L (on ENST00000310418 / NM_007097.5; = p.Q206L on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220967; called by muse, mutect2
- CNNM1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs761658293, COSV63202446; called by muse, mutect2, varscan2
- CNOT1 | c.6352T>A p.C2118S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99801151; called by muse, mutect2, varscan2
- CNOT11 | c.1335+2T>C p.X445_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99179379; called by muse, varscan2
- CNPPD1 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99841362; called by muse, mutect2, varscan2
- CNTFR | c.689C>G p.S230W | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100667512; called by muse, mutect2
- CNTFR | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100667618; called by muse, mutect2
- CNTN2 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV59349914; called by muse, mutect2
- CNTROB | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV66607852; called by muse, mutect2, varscan2
- COA8 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915034; called by muse, mutect2
- COG6 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268992012, COSV62995500, COSV62995628; called by muse, varscan2
- COL11A1 | c.642A>C p.E214D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62187524; called by muse, mutect2, varscan2
- COL12A1 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100486458; called by muse, mutect2, varscan2
- COL13A1 | c.1550del p.P517Qfs*9 (on ENST00000398978 / NM_001130103.2; = p.P460Qfs*9 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs770933186, COSV100637433; called by mutect2, pindel, varscan2
- COL26A1 | c.568C>T p.P190S (on ENST00000313669 / NM_001278563.3; = p.P188S on NM_133457.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs1177617299, COSV100562030; called by muse, mutect2, varscan2
- COL27A1 | c.4142A>G p.Q1381R | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100621309; called by muse, mutect2
- COL4A6 | c.4076C>G p.S1359C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as COSV100564993; called by muse, mutect2
- COL6A6 | c.1729C>A p.Q577K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100650900; called by muse, mutect2, varscan2
- COL7A1 | c.1240+2T>A p.X414_splice | Splice Site (SNP) | VAF 19/214 reads (9%) | catalogued as rs1395765132, COSV100097639; called by muse, mutect2
- CPA1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1554411487, COSV99163353; called by muse, mutect2, varscan2
- CPSF1 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.089); catalogued as COSV100574760; called by muse, mutect2, varscan2
- CPT1B | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.102); catalogued as COSV100376834; called by muse, mutect2, varscan2
- CR1L | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99687970; called by muse, mutect2
- CREBBP | c.5551C>A p.R1851S | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99268258, COSV99271875; called by muse, mutect2
- CRELD2 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1360630712, COSV100078266; called by muse, mutect2, varscan2
- CRTC1 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119578; called by muse, mutect2
- CRTC3 | c.835A>T p.N279Y | Missense Mutation (SNP) | VAF 90/491 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99185807; called by muse, mutect2, varscan2
- CRYM | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV99561918; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.5276A>G p.H1759R (on ENST00000297405 / NM_001363185.1; = p.H1655R on NM_052900.3) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.065); catalogued as rs1043567143, COSV99846860; called by muse, mutect2
- CSRNP3 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs376805913, COSV100084955; called by muse, mutect2, varscan2
- CSRP1 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV100384580; called by muse, mutect2
- CTSV | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs192103728, COSV99414440; called by muse, mutect2, varscan2
- CYLC2 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100872578, COSV66336368; called by muse, mutect2, varscan2
- CYP27B1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56983977, COSV99141652; called by muse, mutect2, varscan2
- CYTH2 | c.814G>A p.G272S (on ENST00000427476; = p.G271S on NM_004228.7) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1236427436, COSV100287353; called by muse, varscan2
- DAAM2 | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1406818181, COSV99226929; called by muse, mutect2, varscan2
- DAAM2 | c.3181C>T p.R1061W (on ENST00000274867 / NM_001201427.2; = p.R1060W on NM_015345.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747447552, COSV51369356; called by muse, mutect2, varscan2
- DAB2IP | c.2263C>T p.R755C (on ENST00000408936; = p.R727C on NM_032552.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761339512, COSV99406289; called by mutect2, varscan2
- DAOA | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100298903; called by muse, mutect2, varscan2
- DAPK1 | c.3944G>A p.R1315H | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as rs368364961; called by muse, mutect2, varscan2
- DAZAP1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51835143; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCAF13 | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52572792; called by muse, mutect2, varscan2
- DCST1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs779688952, COSV55060939; called by muse, mutect2, varscan2
- DCTN5 | c.27_29del p.N9del | In Frame Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs779696050; called by pindel, varscan2
- DDX24 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 24/214 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV100428127; called by muse, mutect2, varscan2
- DDX60L | c.4703T>C p.V1568A | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99488407; called by muse, mutect2
- DECR2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs141623402, COSV99557296; called by muse, mutect2, varscan2
- DEF6 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs767334980, COSV100359523; called by muse, mutect2, varscan2
- DENND1C | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101200249; called by muse, mutect2
- DENND5A | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100065185; called by muse, mutect2, varscan2
- DENND6B | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV101306111; called by muse, mutect2, varscan2
- DHX34 | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs148368794; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX9 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100841512; called by muse, mutect2, varscan2
- DIPK1B | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as COSV100765508; called by muse, mutect2, varscan2
- DIPK2A | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV100237448; called by muse, mutect2, varscan2
- DISP1 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759714329, COSV52658475; called by muse, mutect2, varscan2
- DMAP1 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV100261856; called by muse, mutect2, varscan2
- DMRTA2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1369359407, COSV101288903; called by muse, mutect2
- DNAH1 | c.7847A>G p.Y2616C | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101327012; called by muse, mutect2
- DNAH17 | c.8338G>A p.V2780M | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.28); catalogued as rs748917704, COSV101103400; called by muse, mutect2, varscan2
- DNAH3 | c.5951T>C p.M1984T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs761445310, COSV99770457; called by muse, mutect2, varscan2
- DNAJB4 | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV100883495; called by muse, mutect2
- DNAJC27 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs746614892, COSV53094248; called by muse, mutect2, varscan2
- DNMBP | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60628478; called by muse, mutect2, varscan2
- DNMT1 | c.2587T>C p.Y863H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100533034; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK3 | c.5638G>A p.G1880S | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.998); catalogued as rs749925387, COSV56501857; called by muse, mutect2, varscan2
- DOP1A | c.5272C>T p.R1758C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1156431280, COSV52710851; called by muse, mutect2, varscan2
- DPF2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV99361931; called by muse, mutect2, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs748560644; called by pindel, varscan2
- DPP9 | c.2084del p.N695Tfs*27 (on ENST00000598800; = p.N724Tfs*27 on NM_139159.5) | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as COSV53591119; called by mutect2, pindel
- DPP9 | c.448C>A p.L150I (on ENST00000598800; = p.L179I on NM_139159.5) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as COSV99506486; called by muse, mutect2, varscan2
- DPYD | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV100929377; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 26/222 reads (12%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DST | c.16790T>G p.L5597R (on ENST00000361203 / NM_001374722.1; = p.L3294R on NM_015548.5) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.671); catalogued as COSV99759731; called by muse, mutect2, varscan2
- DTX2 | c.310T>G p.S104A | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100184832; called by muse, mutect2
- DUS4L-BCAP29 | c.1646A>G p.H549R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1041495692, COSV99143754; called by muse, mutect2, varscan2
- DUSP22 | c.430C>A p.H144N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100739929, COSV60525757; called by muse, mutect2
- DYNC1H1 | c.13595A>C p.N4532T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.393); catalogued as COSV100795365, COSV64137371; called by muse, mutect2, varscan2
- DYNC2I2 | c.1528T>C p.W510R | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100823988; called by muse, mutect2, varscan2
- DYSF | c.3643G>A p.A1215T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99250279; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs746509911; called by mutect2, varscan2
- EBAG9 | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV100520906; called by muse, mutect2, varscan2
- ECM1 | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100682270; called by muse, mutect2, varscan2
- EDC4 | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100739290; called by muse, mutect2, varscan2
- EEF1A2 | c.1229T>C p.M410T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99419866; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs753109456, COSV100103771; called by muse, mutect2, varscan2
- EHD4 | c.1603A>T p.K535* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99588331; called by muse, mutect2, varscan2
- EIF2B4 | c.1516A>G p.M506V (on ENST00000347454 / NM_001034116.2; = p.M505V on NM_015636.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV100730756; called by muse, mutect2, varscan2
- EIF4G3 | c.4082A>G p.H1361R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99945606; called by muse, mutect2, varscan2
- ELFN2 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101297635; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | catalogued as rs759858342; called by mutect2, varscan2
- EML1 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99215609; called by muse, mutect2
- EML3 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.883); catalogued as rs368236432; called by muse, varscan2
- EML3 | c.1432T>C p.S478P | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99610292; called by muse, varscan2
- ENKD1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 61/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99537982; called by muse, mutect2, varscan2
- ENPP2 | c.1564G>A p.A522T (on ENST00000075322 / NM_001040092.3; = p.A574T on NM_006209.5) | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs764975897, COSV99309319; called by muse, mutect2, varscan2
- ENTHD1 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100289111; called by muse, varscan2
- EP300 | c.6850A>G p.M2284V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV54326050; called by muse, mutect2
- EPB41L2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs375486728; called by muse, mutect2, varscan2
- EPB41L3 | c.2649G>T p.Q883H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.289); catalogued as COSV100550163; called by muse, mutect2, varscan2
- EPG5 | c.3506T>C p.M1169T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99958055; called by muse, mutect2, varscan2
- EPHA1 | c.396T>G p.D132E | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV99314655; called by muse, mutect2, varscan2
- EPHA6 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV67573197; called by muse, mutect2, varscan2
- EPHA7 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100992523; called by muse, mutect2, varscan2
- EPHB1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); catalogued as rs771145808, COSV101214339, COSV67662602; called by muse, mutect2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPO | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs781324278, COSV53160987; called by muse, mutect2, varscan2
- EPS15L1 | c.2209A>G p.S737G | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1453616752, COSV99933660; called by muse, mutect2, varscan2
- ERBB3 | c.1958T>A p.V653E | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99917806; called by muse, mutect2, varscan2
- ERBB3 | c.2654T>C p.F885S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1437489759, COSV99917808; called by muse, mutect2
- ERBIN | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99397770; called by muse, mutect2, varscan2
- ERC2 | c.1076A>C p.E359A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55603947; called by muse, mutect2, varscan2
- ERCC2 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs559154781, COSV55544679; ClinVar: not provided; called by muse, mutect2, varscan2
- ERCC6 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV100876183; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs780487406; called by mutect2, pindel
- ESPL1 | c.1388T>A p.L463* | Nonsense Mutation (SNP) | VAF 101/498 reads (20%) | catalogued as COSV99229739; called by muse, mutect2, varscan2
- ESR2 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99963844; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV4 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018248763, COSV99292608; called by muse, mutect2, varscan2
- EXD3 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs374548762; called by muse, mutect2, varscan2
- EXOSC10 | c.1012T>G p.F338V | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100442879; called by muse, mutect2, varscan2
- EYA4 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100766321; called by muse, mutect2, varscan2
- F2 | c.1733T>G p.F578C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV100319683; called by muse, mutect2, varscan2
- FADS3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.041); catalogued as COSV99605423, COSV99605490; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM135B | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99358097; called by muse, mutect2, varscan2
- FAM160A2 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99792483; called by muse, mutect2, varscan2
- FAM166A | c.715A>T p.M239L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100458183, COSV61119213; called by muse, mutect2, varscan2
- FAM166A | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100458185; called by muse, mutect2, varscan2
- FAM186B | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99220246; called by muse, mutect2, varscan2
- FAM193A | c.2068T>C p.S690P | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100219570; called by muse, mutect2, varscan2
- FAM71A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs773097173, COSV54236120; called by muse, mutect2, varscan2
- FAN1 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs758141872, COSV62950419; called by muse, mutect2, varscan2
- FANCD2 | c.3823T>C p.F1275L | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV99812424; called by muse, mutect2, varscan2
- FAT1 | c.7819T>C p.S2607P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV71675298; called by muse, mutect2, varscan2
- FAU | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV99658177; called by muse, mutect2
- FBH1 | c.2823G>T p.L941F (on ENST00000362091 / NM_178150.3; = p.L992F on NM_032807.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV100758938; called by muse, mutect2, varscan2
- FBN2 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104390298, COSV99330509; called by muse, mutect2, varscan2
- FBN3 | c.4226C>T p.A1409V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs371026092; called by muse, mutect2, varscan2
- FBXO11 | c.1855G>T p.G619* (on ENST00000403359 / NM_001190274.2; = p.G535* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | catalogued as COSV100319975; called by muse, mutect2
- FBXO24 | c.1094G>A p.G365D (on ENST00000241071 / NM_033506.3; = p.G403D on NM_012172.5) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV53830936, COSV99575660; called by muse, mutect2, varscan2
- FBXO38 | c.2675G>A p.R892H (on ENST00000340253 / NM_205836.3; = p.R817H on NM_030793.5) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs183483408, COSV57033345; ClinVar: uncertain significance; called by muse, varscan2
- FEN1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs778764875, COSV99952963; called by muse, mutect2, varscan2
- FGD5 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as rs369369417; called by muse, varscan2
- FGFR4 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1289445624, COSV99449724; called by muse, mutect2, varscan2
- FGFR4 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs760787865; called by muse, mutect2
- FHDC1 | c.3197A>T p.Q1066L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99471683; called by muse, mutect2, varscan2
- FHL1 | c.611A>C p.E204A | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100600849; called by muse, mutect2, varscan2
- FLOT2 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV101204809; called by muse, mutect2, varscan2
- FLYWCH2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99567370; called by muse, mutect2, varscan2
- FOXN2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs138143881, COSV61319304; called by muse, mutect2, varscan2
- FOXN4 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100142291; called by muse, mutect2
- FOXP4 | c.1319G>A p.R440Q (on ENST00000307972 / NM_001012426.1; = p.R427Q on NM_138457.3) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs576059149, COSV57220668; called by muse, mutect2, varscan2
- FOXP4 | c.1802T>A p.L601Q (on ENST00000307972 / NM_001012426.1; = p.L588Q on NM_138457.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV100333020; called by muse, mutect2
- FPGT-TNNI3K | c.845del p.F282Sfs*15 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs751624085; called by mutect2, pindel, varscan2
- FRMD7 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV100049279; called by muse, mutect2, varscan2
- FRY | c.7028G>A p.R2343Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs368168190; called by mutect2, varscan2
- FSTL4 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs374211071; called by muse, mutect2, varscan2
- FUT3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757862405, COSV54605943; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | catalogued as rs756304971; called by mutect2, varscan2
- GAB1 | c.1705del p.R569Dfs*24 | Frame Shift Del (DEL) | VAF 32/162 reads (20%) | catalogued as rs1314151809, COSV53755907; called by mutect2, varscan2
- GABBR1 | c.916T>C p.W306R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590040; called by muse, mutect2, varscan2
- GABRB3 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100161688; called by muse, mutect2, varscan2
- GALNS | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99243440; called by muse, mutect2, varscan2
- GALT | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs111033766, CM102666, CM990664; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GAS2L1 | c.1960del p.R654Afs*48 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs752503735; called by mutect2, pindel, varscan2
- GBP1 | c.1172del p.K391Sfs*28 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as rs777277713; called by mutect2, pindel
- GCFC2 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100319720; called by muse, mutect2
- GCM2 | c.1052T>G p.F351C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV101069618; called by muse, mutect2, varscan2
- GCNT1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs142199715; called by muse, mutect2
- GGT7 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100322187; called by muse, mutect2, varscan2
- GLA | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002608, CM003752, CM085978, COSV99516524, COSV99516586; called by muse, mutect2
- GLB1L | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.274); catalogued as COSV99850879; called by muse, mutect2, varscan2
- GLCCI1 | c.733A>G p.K245E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99780737; called by muse, mutect2, varscan2
- GLDC | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100394575; called by muse, mutect2, varscan2
- GLI2 | c.2131C>T p.R711W (on ENST00000361492 / NM_001374353.1; = p.R728W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as rs1397888063, COSV100084249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLMN | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100950190; called by muse, mutect2, varscan2
- GLRA1 | c.191del p.P64Qfs*2 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | catalogued as COSV51012399, COSV51017926; called by mutect2, pindel, varscan2
- GLS2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as rs754953103, COSV100358479; called by muse, mutect2, varscan2
- GLTP | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV59174096; called by muse, mutect2, varscan2
- GNA13 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); catalogued as COSV101457510; called by muse, mutect2, varscan2
- GON4L | c.1014+2T>G p.X338_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99675700; called by muse, mutect2, varscan2
- GP5 | c.1570T>C p.F524L | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100541019; called by muse, varscan2
- GPBAR1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs202136704; called by muse, mutect2, varscan2
- GPD1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs151058941; called by muse, mutect2, varscan2
- GPR1 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101329867; called by muse, mutect2, varscan2
- GPR153 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs370733910; called by muse, mutect2, varscan2
- GPR17 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99760761; called by muse, mutect2
- GPR173 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100212417; called by muse, mutect2
- GPR179 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs750988170; called by muse, mutect2, varscan2
- GPR27 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99816680; called by muse, mutect2
- GPR37L1 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs374873137; called by mutect2, varscan2
- GPRC5B | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs773009862, COSV100315290, COSV56027601; called by muse, mutect2, varscan2
- GPRC5C | c.1265T>C p.L422P (on ENST00000652232; = p.L377P on NM_018653.4) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100703000; called by muse, mutect2
- GPRC6A | c.1160A>C p.K387T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100114765; called by muse, mutect2
- GPRIN3 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV100310996; called by muse, mutect2, varscan2
- GPSM2 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99915582; called by muse, mutect2, varscan2
- GPSM2 | c.1798A>C p.I600L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV99915583; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM5 | c.3329C>T p.T1110M (on ENST00000305447 / NM_001143831.2; = p.T1078M on NM_000842.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.988); catalogued as COSV59591373; called by muse, mutect2
- GSK3A | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV99725454; called by muse, mutect2, varscan2
- GTF3C1 | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755819102, COSV100649687, COSV62239860; called by muse, mutect2, varscan2
- GTF3C5 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775308894, COSV100565558; called by muse, mutect2, varscan2
- GUCA2B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867354527, COSV65367901; called by muse, mutect2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- GYS2 | c.1209del p.K403Nfs*7 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs777954647, COSV53922451; called by mutect2, pindel, varscan2
- HADHA | c.2279A>G p.K760R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); catalogued as COSV101024180; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | catalogued as rs34558496; called by mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HEATR5A | c.5724A>C p.K1908N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV101120519; called by muse, mutect2, varscan2
- HEBP1 | c.203del p.G68Afs*11 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as COSV50009616; called by mutect2, varscan2
- HECTD4 | c.7235C>T p.P2412L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761593797, COSV66398717; called by muse, mutect2, varscan2
- HEPH | c.1907T>C p.M636T (on ENST00000343002; = p.M369T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100295661; called by muse, mutect2, varscan2
- HEPHL1 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765449710, COSV59889184; called by muse, mutect2, varscan2
- HGFAC | c.1362del p.R455Gfs*19 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs761929917; called by mutect2, pindel
- HIPK1 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1024678990, COSV100479641; called by muse, mutect2, varscan2
- HIPK4 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99397053; called by muse, mutect2
- HIVEP3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751390922, COSV56018437; called by muse, mutect2
- HMCN1 | c.11336G>T p.G3779V | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635329; called by muse, mutect2
- HOOK2 | c.2153A>C p.K718T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99244664; called by muse, mutect2, varscan2
- HORMAD1 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777923537, COSV59270206; called by muse, mutect2, varscan2
- HPF1 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101097705; called by muse, mutect2, varscan2
- HPS5 | c.611+1G>T p.X204_splice (on ENST00000349215 / NM_181507.2; = p.X90_splice on NM_007216.4) | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100834480; called by muse, mutect2, varscan2
- HRNR | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100913907; called by muse, mutect2, varscan2
- HSP90B1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368374645; called by muse, varscan2
- HSPA2 | c.1864A>G p.S622G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1566643513, COSV55968677; called by muse, mutect2, varscan2
- HSPG2 | c.3130G>A p.A1044T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV101021191; called by muse, mutect2, varscan2
- HUNK | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs377533874; called by muse, mutect2, varscan2
- HUWE1 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99474113; called by muse, mutect2, varscan2
- ICA1 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.04); catalogued as COSV99655872; called by muse, mutect2, varscan2
- IFT140 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs1159315989, COSV68488139; called by muse, mutect2, varscan2
- IFT172 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99563272; called by muse, mutect2
- IGF2BP3 | c.1320+2T>C p.X440_splice | Splice Site (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99325819; called by muse, mutect2, varscan2
- IGLV3-16 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs761271451; called by muse, mutect2, varscan2
- IL15 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV99650826; called by muse, mutect2, varscan2
- IL17C | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV99733394; called by muse, mutect2, varscan2
- IL17RC | c.29T>A p.L10* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV99925266; called by muse, mutect2
- IL18R1 | c.1237T>C p.C413R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99295482; called by muse, mutect2, varscan2
- IL4R | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99405386; called by muse, mutect2, varscan2
- IQCH | c.1347G>T p.R449S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100246321, COSV60060099; called by muse, mutect2, varscan2
- IRF2 | c.602A>C p.Q201P | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV101165906; called by muse, mutect2, varscan2
- IRF2BP2 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100784404; called by muse, mutect2, varscan2
- IRF7 | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99213407; called by muse, mutect2
- IRGQ | c.1355del p.P452Qfs*100 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs1331665578; called by mutect2, pindel, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs761880048; called by mutect2, varscan2
- ISYNA1 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs752367466, COSV54211370; called by muse, mutect2, varscan2
- ITIH3 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV101407135; called by muse, mutect2, varscan2
- ITLN2 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV100600756; called by muse, mutect2, varscan2
- ITPRID2 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs779882988, COSV100238888, COSV57474981; called by muse, mutect2, varscan2
- JADE3 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.049); catalogued as rs781883396, COSV99510269; called by muse, mutect2, varscan2
- JAK3 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV101513018; called by muse, mutect2, varscan2
- JPH3 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs772668984, COSV99413969; called by muse, mutect2
- KANK2 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100763382; called by muse, mutect2, varscan2
- KATNB1 | c.1804T>C p.S602P | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101109349; called by muse, mutect2
- KCNA10 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871491; called by muse, mutect2, varscan2
- KCNA5 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99364191; called by muse, mutect2, varscan2
- KCNB2 | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV101579001; called by muse, mutect2, varscan2
- KCNH7 | c.3206del p.P1069Qfs*6 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs1266218958; called by mutect2, pindel, varscan2
- KCNH8 | c.3171G>T p.Q1057H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100111001; called by muse, mutect2, varscan2
- KCNJ10 | c.305del p.P102Rfs*96 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as rs765409185; called by mutect2, pindel, varscan2
- KCNJ5 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100610803; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs753256170; called by mutect2, pindel
- KCNV1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV99819421; called by muse, mutect2, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs759860142; called by mutect2, pindel, varscan2
- KIAA0100 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV101197409; called by muse, mutect2
- KIAA1549 | c.4900G>A p.V1634I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750742481, COSV54312105; called by muse, mutect2, varscan2
- KIAA1614 | c.149dup p.R51Kfs*99 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | catalogued as rs771572430; called by pindel, varscan2
- KIF20A | c.64_65insA p.P22Hfs*4 | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | catalogued as COSV99137619; called by mutect2, pindel, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs753332734; called by mutect2, varscan2
- KIF2C | c.541T>G p.S181A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100945858; called by muse, mutect2
- KIF3C | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99267906; called by muse, mutect2
- KIF6 | c.2442T>A p.N814K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99756851, COSV99760601; called by muse, mutect2, varscan2
- KIF9 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as rs114109244, COSV55519383; called by muse, mutect2, varscan2
- KIFC1 | c.1681del p.L561Sfs*16 | Frame Shift Del (DEL) | VAF 48/297 reads (16%) | catalogued as rs1562839389; called by mutect2, pindel, varscan2
- KIRREL1 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs755272666, COSV100780100; called by muse, mutect2, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel, varscan2
- KLHDC7A | c.1996A>T p.K666* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101272846; called by muse, varscan2
- KLHL25 | c.859T>G p.C287G | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100563725; called by muse, mutect2, varscan2
- KLHL31 | c.551T>A p.L184Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100911853, COSV63882336; called by muse, mutect2
- KLHL36 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs768073602, COSV99257083; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs780868475, COSV99386254; called by muse, mutect2, varscan2
- KMT2E | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as COSV99996961; called by muse, mutect2, varscan2
- KMT2E | c.4364C>T p.T1455M | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs370792273; called by muse, mutect2, varscan2
- KMT5B | c.2461T>C p.Y821H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.222); catalogued as rs1298409759, COSV100430448; called by muse, mutect2, varscan2
- KMT5B | c.1559A>T p.N520I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100430449; called by muse, mutect2, varscan2
- KRT12 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52431846; called by muse, mutect2, varscan2
- KRT18 | c.797A>T p.E266V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101184122; called by muse, mutect2, varscan2
- KRT222 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV101229485; called by muse, mutect2, varscan2
- KRT40 | c.1291T>G p.L431V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100898905; called by muse, mutect2, varscan2
- KRT74 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs771938985, COSV99977682; called by muse, mutect2, varscan2
- KRTAP10-8 | c.496T>C p.C166R | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100555397; called by muse, mutect2, varscan2
- LAMA5 | c.1108T>A p.Y370N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99439952, COSV99442149; called by muse, mutect2, varscan2
- LAMB4 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV52723830; called by muse, mutect2, varscan2
- LARP1 | c.2351G>A p.R784H (on ENST00000518297 / NM_033551.3; = p.R707H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs766791311, COSV60429251; called by muse, mutect2, varscan2
- LAT2 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 19/179 reads (11%) | catalogued as COSV99305945; called by muse, mutect2, varscan2
- LATS2 | c.2554del p.D852Tfs*3 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV66875447; called by mutect2, pindel, varscan2
- LCOR | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100603864; called by muse, mutect2, varscan2
- LDHA | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs1488155815, COSV99908408; called by muse, mutect2
- LEFTY2 | c.790T>C p.C264R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs545519108, COSV64746366; called by muse, mutect2, varscan2
- LHB | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs746167425, COSV99669256; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs775423572; called by mutect2, varscan2
- LHX8 | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV99634365; called by muse, mutect2, varscan2
- LIG3 | c.989del p.F330Sfs*16 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | catalogued as rs765883512; called by mutect2, pindel, varscan2
- LILRB1 | c.634G>A p.G212R (on ENST00000427581; = p.G176R on NM_006669.6) | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as COSV100207847; called by muse, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | catalogued as rs748712732; called by mutect2, varscan2
- LPA | c.5469del p.C1824Vfs*27 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as rs752960449; called by mutect2, pindel, varscan2
- LRP1 | c.8266A>G p.S2756G | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.13); catalogued as COSV99677142; called by muse, mutect2, varscan2
- LRP1B | c.8791T>G p.L2931V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV101260568; called by muse, mutect2, varscan2
- LRP2BP | c.106+2T>C p.X36_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV60749667; called by muse, mutect2, varscan2
- LRP4 | c.3550A>G p.T1184A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV101066863; called by muse, mutect2, varscan2
- LRRC36 | c.1551del p.I518Sfs*47 | Frame Shift Del (DEL) | VAF 79/464 reads (17%) | catalogued as rs1471620719, COSV52079364, COSV52079614; called by mutect2, pindel, varscan2
- LRRC37B | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs760570369, COSV100496525; called by muse, mutect2, varscan2
- LRRC41 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs939187238, COSV58439463, COSV58440171; called by muse, mutect2, varscan2
- LRRC46 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as rs748743875, COSV51635956; called by muse, mutect2, varscan2
- LRRN4CL | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as rs1435281354, COSV54016148; called by muse, mutect2, varscan2
- LRSAM1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as COSV55939718; called by muse, mutect2, varscan2
- LRTOMT | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs755256346, COSV99194459; called by muse, mutect2, varscan2
- LSS | c.110C>A p.T37N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100711043; called by muse, mutect2
- LTBP1 | c.1618C>A p.H540N (on ENST00000404816 / NM_206943.4; = p.H214N on NM_000627.4) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100617917; called by muse, mutect2, varscan2
- LTBP3 | c.2533A>T p.N845Y | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99534594; called by muse, mutect2, varscan2
- LTN1 | c.3944T>A p.I1315N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100798193; called by muse, mutect2, varscan2
- LY6E | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1471924016, COSV99465182; called by muse, mutect2, varscan2
- LY6G5C | c.563T>C p.M188T (on ENST00000375863; = p.M113T on NM_025262.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV101020855; called by muse, mutect2, varscan2
- LY96 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99514710; called by muse, mutect2, varscan2
- LZTR1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs747430075, COSV53147792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAB21L2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100462213; called by muse, mutect2, varscan2
- MAB21L3 | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101046492; called by muse, mutect2, varscan2
- MAGEA3 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100939084; called by muse, mutect2, varscan2
- MAGEB4 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1437121381, COSV100854809, COSV100854811; called by muse, mutect2, varscan2
- MAGEE1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs892088909, COSV100819299, COSV63910595; called by muse, mutect2, varscan2
- MAGIX | c.298T>A p.C100S | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.163); catalogued as COSV100891924; called by muse, mutect2, varscan2
- MAK | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs767273634, COSV57568219; called by muse, mutect2, varscan2
- MAP3K4 | c.1285A>T p.I429F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100815665; called by muse, mutect2
- MAPK4 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs554214382, COSV101245965; called by muse, mutect2
- MARCO | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100503830; called by muse, mutect2, varscan2
- MCAM | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as rs755944376, COSV50670780, COSV99875369; called by muse, mutect2, varscan2
- MCM10 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV101098442; called by muse, mutect2, varscan2
- MCPH1 | c.358A>C p.T120P | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100766094; called by muse, mutect2, varscan2
- MED12L | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99854583; called by muse, mutect2, varscan2
- MED14 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100247630; called by muse, mutect2, varscan2
- MED23 | c.3079G>A p.V1027I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs1167434123, COSV100645389; called by muse, mutect2, varscan2
- MEGF10 | c.2153G>A p.C718Y | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57255015, COSV99175601; called by muse, mutect2, varscan2
- MEGF10 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99175605; called by muse, mutect2, varscan2
- MEI1 | c.3578T>C p.V1193A | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100300318; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 20/81 reads (25%) | catalogued as rs745891632; called by mutect2, varscan2
- METTL3 | c.1703G>T p.R568M | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs17854735, COSV99398582; called by muse, mutect2, varscan2
- METTL8 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100931107; called by muse, mutect2, varscan2
- MFAP1 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs1293668103, COSV99980114; called by muse, mutect2, varscan2
- MFSD9 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762751390, COSV51493104; called by muse, mutect2, varscan2
- MGA | c.9007G>A p.A3003T (on ENST00000219905 / NM_001164273.1; = p.A2794T on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54961488, COSV99581467; called by muse, mutect2, varscan2
- MICAL1 | c.2325G>C p.E775D | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99238160; called by muse, mutect2, varscan2
- MID2 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV99465558; called by muse, mutect2, varscan2
- MIDEAS | c.2150T>C p.V717A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99679224; called by muse, mutect2
- MIEF2 | c.139del p.V47* | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as COSV58944548; called by mutect2, pindel, varscan2
- MIP | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99234409; called by muse, mutect2, varscan2
- MMEL1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56521792; called by muse, mutect2, varscan2
- MMP1 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as COSV100188102; called by muse, mutect2
- MMP14 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1354231014, COSV100314314; called by muse, mutect2, varscan2
- MMP20 | c.977A>G p.H326R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1392165269, COSV99497963; called by muse, mutect2, varscan2
- MMP3 | c.298T>G p.F100V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100242896, COSV100243022; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MMUT | c.2100G>A p.M700I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV51272751; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MNT | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 71/401 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs563339380, COSV99438271; called by muse, mutect2, varscan2
- MORC4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs759643903; called by mutect2, varscan2
- MRGPRX4 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100049844; called by muse, mutect2
- MRPL17 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV99996927; called by muse, mutect2, varscan2
- MRPS23 | c.421-2A>G p.X141_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100551488; called by muse, mutect2, varscan2
- MRPS5 | c.336del p.G113Efs*14 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | catalogued as rs1558684714; called by mutect2, pindel, varscan2
- MTAP | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs778107183, COSV101205509; called by muse, mutect2, varscan2
- MTCH2 | c.661T>A p.Y221N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100207119; called by muse, mutect2, varscan2
- MTCL1 | c.3452C>T p.A1151V (on ENST00000306329 / NM_001378206.1; = p.A832V on NM_015210.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs907901357, COSV60403044; called by muse, mutect2, varscan2
- MTOR | c.4871A>G p.Q1624R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); catalogued as rs938233596, COSV100816645; called by muse, mutect2
- MTPAP | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs199777853, COSV99554303; called by muse, mutect2, varscan2
- MTREX | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57924628, COSV57927567, COSV57929924; called by muse, mutect2, varscan2
- MUC16 | c.30015A>C p.E10005D | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV101201505; called by muse, mutect2, varscan2
- MUC16 | c.24931A>G p.M8311V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV101201507; called by muse, mutect2, varscan2
- MUC16 | c.23136dup p.S7713Lfs*40 | Frame Shift Ins (INS) | VAF 16/77 reads (21%) | catalogued as rs1568814554; called by mutect2, varscan2
- MUC16 | c.4127T>C p.L1376P | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV101201510; called by muse, mutect2, varscan2
- MUC17 | c.8810C>A p.T2937N | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV100074968; called by muse, mutect2, varscan2
- MUC2 | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs765413779; called by muse, mutect2, varscan2
- MUC5AC | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); catalogued as rs1453413413, COSV100650694; called by muse, mutect2, varscan2
- MUC5B | c.10337del p.P3446Qfs*45 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as COSV101500072; called by mutect2, pindel
- MUC5B | c.14809T>C p.S4937P | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101500739; called by muse, mutect2, varscan2
- MUC5B | c.15322C>T p.R5108C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs777182861, COSV71590428; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH10 | c.5303C>T p.T1768I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV99346306; called by muse, mutect2, varscan2
- MYH7 | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100806596; called by muse, varscan2
- MYH8 | c.5354T>C p.M1785T | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV101238760; called by muse, mutect2, varscan2
- MYH9 | c.4651A>G p.T1551A | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.045); catalogued as COSV99339798; called by muse, mutect2, varscan2
- MYOZ3 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.197); catalogued as COSV99770891; called by muse, mutect2, varscan2
- MYT1 | c.3155A>C p.Q1052P | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100115424; called by muse, mutect2, varscan2
- MZF1 | c.1311A>T p.E437D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV99285454; called by muse, mutect2
- N4BP3 | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99200811; called by muse, mutect2, varscan2
- NAIF1 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100895875; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV3 | c.5222C>T p.P1741L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148932437, COSV57090810, COSV57116543; called by muse, mutect2, varscan2
- NCDN | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100357676; called by muse, mutect2
- NCOA7 | c.1058A>G p.K353R | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); catalogued as COSV99997630; called by muse, mutect2, varscan2
- NCOR2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100657108, COSV100657861; called by muse, mutect2, varscan2
- NECAP2 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 35/179 reads (20%) | catalogued as rs767888125, COSV100452374; called by muse, mutect2, varscan2
- NEXMIF | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.301); catalogued as COSV50025594, COSV99281807; called by muse, mutect2, varscan2
- NFE2L1 | c.510+2T>G p.X170_splice | Splice Site (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100671718; called by muse, mutect2, varscan2
- NFIA | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100964169; called by muse, mutect2
- NFS1 | c.871A>G p.M291V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100932009; called by muse, mutect2, varscan2
- NFU1 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as COSV100361353; called by muse, mutect2
- NFYB | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as rs747482721, COSV53530182; called by muse, mutect2, varscan2
- NHLRC2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1564849146, COSV100800483; called by muse, mutect2, varscan2
- NIBAN1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs145818889; called by muse, mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 30/209 reads (14%) | catalogued as rs763440516; called by mutect2, varscan2
- NKX3-2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101219981; called by mutect2, varscan2
- NLRP12 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.349); catalogued as rs762604819, COSV100145877; called by muse, mutect2, varscan2
- NME4 | c.475del p.A159Pfs*15 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | catalogued as rs770464890; called by mutect2, pindel, varscan2
- NOD2 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV100318853; called by muse, mutect2
- NOTUM | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1233640398, COSV101293828; called by muse, mutect2
- NPBWR1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs1430608035, COSV58698017; called by muse, mutect2, varscan2
- NPHS1 | c.3397A>C p.T1133P | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100800251; called by muse, mutect2, varscan2
- NPTXR | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs375259496; called by muse, mutect2, varscan2
- NPY2R | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279901; called by muse, mutect2, varscan2
- NSD2 | c.2518+2T>C p.X840_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100373875; called by muse, mutect2
- NT5C1A | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99348668; called by muse, mutect2, varscan2
- NTRK1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374799164; called by muse, mutect2, varscan2
- NUCB1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99618132; called by muse, mutect2, varscan2
- NUDT5 | c.266del p.G89Afs*4 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs1564424334; called by mutect2, pindel, varscan2
- NUP133 | c.3260A>G p.D1087G | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV99773445; called by muse, mutect2, varscan2
- NUP98 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100263413; called by muse, mutect2, varscan2
- NUTM2A | c.1570A>G p.M524V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV101095771; called by mutect2, varscan2
- OBSCN | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52780401; called by muse, mutect2, varscan2
- OBSL1 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.876); catalogued as rs767824497, COSV99217444; called by muse, varscan2
- OFD1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100407134; called by muse, mutect2, varscan2
- OLFML2A | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as COSV99992875; called by muse, mutect2
- OPHN1 | c.1183A>G p.N395D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as rs749837689, COSV100830755; called by muse, mutect2, varscan2
- OPLAH | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV101470930; called by muse, varscan2
- OR10G8 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1181718909, COSV101461877; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 56/377 reads (15%) | catalogued as rs1566497842; called by mutect2, varscan2
- OR4P4 | c.315dup p.G106Wfs*14 | Frame Shift Ins (INS) | VAF 24/115 reads (21%) | catalogued as rs748398423; called by mutect2, varscan2
- OR5F1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1284311119, COSV99558914; called by muse, mutect2, varscan2
- OR5H14 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV101454286; called by muse, mutect2, varscan2
- OR5L2 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs372269463, COSV101004410; called by muse, mutect2, varscan2
- OR7D4 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); catalogued as COSV100432869; called by muse, mutect2, varscan2
- OR7G2 | c.384dup p.A129Cfs*14 | Frame Shift Ins (INS) | VAF 15/105 reads (14%) | catalogued as rs750339447; called by pindel, varscan2
- OTOP1 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs547040796; called by muse, mutect2, varscan2
- P3H3 | c.540_542del p.F181del | In Frame Del (DEL) | VAF 29/210 reads (14%) | catalogued as rs781882653; called by pindel, varscan2
- PADI2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs367699636, COSV64945455; called by muse, mutect2, varscan2
- PADI3 | c.1374del p.V459Wfs*17 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | catalogued as rs747531633; called by pindel, varscan2
- PAFAH2 | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100959379; called by muse, mutect2, varscan2
- PAIP2 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV99497380; called by muse, mutect2, varscan2
- PAK2 | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100506330; called by muse, varscan2
- PAK4 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338270086, COSV58945651; called by muse, mutect2, varscan2
- PAQR9 | c.949T>C p.F317L | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as COSV100503923; called by muse, mutect2
- PARP12 | c.1892A>G p.N631S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs919218045, COSV99694260; called by muse, mutect2, varscan2
- PARP14 | c.3965del p.N1322Ifs*26 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs758945932; called by mutect2, varscan2
- PARP4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs758277432, COSV67964417; called by muse, mutect2
- PAX1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs1415574372, COSV68271656; called by muse, mutect2, varscan2
- PAX3 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100399956; called by muse, mutect2, varscan2
- PAX4 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776151854, COSV100490333, COSV58387497; called by muse, mutect2, varscan2
- PCDH19 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867012022, COSV55259918; called by muse, mutect2, varscan2
- PCDH9 | c.2556A>C p.Q852H | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100123360; called by muse, mutect2, varscan2
- PCDHA1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs368549830; called by muse, mutect2, varscan2
- PCDHA1 | c.2108C>A p.A703D | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV100974467; called by muse, mutect2
- PCDHA10 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100254230; called by muse, mutect2, varscan2
- PCDHA8 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65336618; called by muse, mutect2, varscan2
- PCDHGA3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV99546395; called by muse, mutect2, varscan2
- PCGF5 | c.663+1G>A p.X221_splice | Splice Site (SNP) | VAF 28/124 reads (23%) | catalogued as COSV60237786; called by muse, mutect2, varscan2
- PCSK1 | c.1539T>G p.I513M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100227265; called by muse, mutect2, varscan2
- PDCD1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV100545564; called by muse, mutect2, varscan2
- PDE6H | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.873); catalogued as rs753392540, COSV99844057; called by mutect2, varscan2
- PDIA2 | c.755T>G p.V252G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.181); catalogued as COSV99250291; called by muse, mutect2, varscan2
- PEAK1 | c.3117G>T p.Q1039H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100433429; called by muse, mutect2, varscan2
- PFAS | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100119131; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PHF2 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63681940; called by muse, mutect2, varscan2
- PHRF1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1398196971, COSV99213401; called by muse, mutect2, varscan2
- PI4KB | c.2230A>G p.M744V (on ENST00000368873 / NM_001369623.1; = p.M756V on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs373500632; called by muse, mutect2, varscan2
- PIAS3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1553735096, COSV65170954; called by muse, mutect2, varscan2
- PIGG | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99574309; called by muse, mutect2, varscan2
- PIGQ | c.1819T>C p.C607R | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV99216525; called by muse, mutect2
- PIGZ | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99433953; called by muse, mutect2, varscan2
- PIK3R5 | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs540270770, COSV52660215; called by muse, mutect2, varscan2
- PIWIL2 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1474549766, COSV100769537; called by muse, varscan2
- PKP3 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs762556650, COSV100520950; called by muse, mutect2, varscan2
- PLD1 | c.508A>T p.M170L | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100578835; called by muse, mutect2, varscan2
- PLEC | c.1115T>C p.L372P (on ENST00000322810 / NM_201380.4; = p.L262P on NM_000445.5) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518668; called by muse, mutect2, varscan2
- PLOD1 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750991056, COSV52141457; called by muse, mutect2, varscan2
- PLSCR3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV61170631; called by muse, mutect2, varscan2
- PLXNB1 | c.4054C>T p.R1352W | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs745313142, COSV56493281; called by muse, mutect2, varscan2
- PLXNB2 | c.4292A>G p.Q1431R | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834288; called by muse, mutect2
- PNLIP | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100981961, COSV65041424; called by muse, mutect2, varscan2
- PNMA5 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV62625430; called by muse, mutect2, varscan2
- PNPLA6 | c.884G>A p.R295H (on ENST00000414982 / NM_001166111.2; = p.R247H on NM_006702.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55384324; called by mutect2, varscan2
- PNPLA8 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1231226796, COSV57553829; called by muse, mutect2, varscan2
- PODXL2 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs753402032, COSV99230126; called by muse, mutect2, varscan2
- POGZ | c.2433-3del | Splice Region (DEL) | VAF 6/38 reads (16%) | catalogued as rs34455423; called by mutect2, pindel
- POGZ | c.2169C>A p.D723E | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.753); catalogued as COSV99653209; called by muse, mutect2, varscan2
- POLG | c.547del p.E183Rfs*83 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs35065786; called by mutect2, pindel
- POLH | c.1844A>C p.E615A | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100947883; called by muse, mutect2, varscan2
- POLQ | c.4289dup p.L1430Ffs*5 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | catalogued as rs755281591, COSV99951761; called by mutect2, varscan2
- POMC | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.301); catalogued as COSV99256982; called by muse, mutect2, varscan2
- POU3F1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884722; called by muse, mutect2, varscan2
- PPA1 | c.297+1G>C p.X99_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100949964; called by muse, mutect2, varscan2
- PPARD | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867021538, COSV100283209; called by muse, mutect2, varscan2
- PPFIBP1 | c.2345A>G p.N782S (on ENST00000318304 / NM_177444.3; = p.N776S on NM_003622.4) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57293631; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | catalogued as rs1365223299; called by mutect2, varscan2
- PPP1R27 | c.44A>G p.Q15R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100367374; called by muse, mutect2
- PPP2R5C | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.017); catalogued as COSV100159968; called by muse, mutect2, varscan2
- PPP3CB | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV100646266; called by muse, mutect2, varscan2
- PPP4R4 | c.1807T>G p.C603G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.319); catalogued as COSV100429006; called by muse, mutect2, varscan2
- PRKAA1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs375372236; called by muse, mutect2, varscan2
- PRKDC | c.898T>C p.W300R | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100042728; called by muse, mutect2
- PRKRA | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57868727; called by muse, mutect2, varscan2
- PRMT5 | c.1629G>T p.E543D | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV99363154; called by muse, mutect2, varscan2
- PROZ | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100720401; called by muse, mutect2, varscan2
- PRPSAP2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs780059835, COSV52067748; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2B | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100622212; called by muse, mutect2
- PRSS21 | c.905del p.F302Sfs*17 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs760493970; called by mutect2, pindel, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSD4 | c.3130T>C p.Y1044H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as COSV99831458; called by muse, mutect2, varscan2
- PSG8 | c.107T>A p.V36D | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100126601; called by muse, mutect2, varscan2
- PSMB11 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV101273631; called by muse, mutect2
- PSMC6 | c.365T>A p.M122K (on ENST00000612399; = p.M108K on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV101471213; called by muse, mutect2
- PSMD2 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100031986; called by muse, mutect2, varscan2
- PSMD5 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV99270926; called by muse, mutect2, varscan2
- PSMD7 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99542820; called by muse, mutect2, varscan2
- PTCH1 | c.4187del p.G1396Dfs*56 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | catalogued as COSV59482481; called by mutect2, pindel, varscan2
- PTDSS2 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs756683426; called by muse, mutect2
- PTH1R | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs73067029, COSV100481169; called by muse, mutect2, varscan2
- PTK2B | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1413720793, COSV100594427; called by muse, mutect2, varscan2
- PTPRM | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764281560, COSV100160230; called by muse, mutect2, varscan2
- PTPRN2 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs142388788; called by muse, mutect2, varscan2
- PTPRO | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs201019396, COSV55503205; called by muse, mutect2, varscan2
- PTTG1IP | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs147066771, COSV100445971; called by muse, mutect2, varscan2
- QARS1 | c.1160T>A p.F387Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070259; called by muse, mutect2, varscan2
- R3HCC1L | c.169_170del p.S57Pfs*6 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | catalogued as rs1248976790; called by pindel, varscan2
- RAB3A | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770289807, COSV99718119; called by muse, mutect2, varscan2
- RAB42 | c.242dup p.V82Cfs*38 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs753536519; called by mutect2, varscan2
- RAP1GAP | c.1831A>G p.T611A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99265882; called by muse, mutect2, varscan2
- RAPH1 | c.2288C>A p.P763H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV99864450; called by muse, mutect2, varscan2
- RASA1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99170128, COSV99170700; called by muse, mutect2, varscan2
- RASAL1 | c.146T>A p.L49Q | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99922113; called by muse, mutect2, varscan2
- RASGEF1A | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100988722; called by muse, mutect2, varscan2
848 further variants in this file (488 protein-altering or splice-affecting, 314 silent, 46 other) are not listed here.
